Somatic mutation profile of cancer-model specimen HCM-CSHL-0608-C17-85A (3D Organoid, passage 4; aliquot HCM-CSHL-0608-C17-85A-01D-A79M-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0608-C17, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical carcinoid tumor; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 39.8 years (14,534 days).
Specimen HCM-CSHL-0608-C17-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d2f32bb-5000-427b-8c8d-c428d172e38b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0608-C17-10A (Blood Derived Normal), aliquot HCM-CSHL-0608-C17-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34e2d314-682b-47c9-95e7-0ea001aad3b3

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 3, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.4066C>A p.P1356T | Missense Mutation (SNP) | VAF 204/425 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV101166064; called by muse, mutect2, varscan2
- AFF3 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745357528, COSV100420029; called by muse, mutect2, varscan2
- AHNAK2 | c.12835C>T p.R4279W | Missense Mutation (SNP) | VAF 416/862 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs536680955, COSV60916830; called by muse, mutect2, varscan2
- AMBRA1 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 259/282 reads (92%) | catalogued as rs1354023827; called by muse, mutect2, varscan2
- AMOTL2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 172/357 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs369381825; called by muse, mutect2, varscan2
- ARID2 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 153/330 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57596651, COSV57609951; called by muse, mutect2, varscan2
- ARID2 | c.4888C>T p.Q1630* | Nonsense Mutation (SNP) | VAF 160/349 reads (46%) | catalogued as COSV57599876; called by muse, mutect2, varscan2
- C8A | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs753968787, COSV63486112; called by muse, mutect2, varscan2
- CDKN1B | c.593C>G p.T198R | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1197510010; called by muse, mutect2, varscan2
- DHX15 | c.2024G>C p.R675P | Missense Mutation (SNP) | VAF 307/470 reads (65%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100391765; called by muse, mutect2, varscan2
- DLC1 | c.1588G>A p.E530K (on ENST00000276297 / NM_001348081.2; = p.E93K on NM_006094.5) | Missense Mutation (SNP) | VAF 34/462 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV52313065; called by muse, mutect2
- DXO | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 107/569 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV61715311; called by muse, mutect2, varscan2
- LRRK2 | c.6677T>G p.V2226G | Missense Mutation (SNP) | VAF 165/351 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV54148509; called by muse, mutect2, varscan2
- MUC5B | c.11207G>C p.G3736A | Missense Mutation (SNP) | VAF 217/719 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.023); catalogued as rs769841042; called by muse, mutect2, varscan2
- PRKCD | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 177/392 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as rs781980599, COSV57848431; called by muse, mutect2, varscan2
- SLC19A3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 231/515 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367620430; called by muse, mutect2, varscan2
- SULF2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 253/580 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs190217262, COSV63414310; called by muse, mutect2, varscan2
- SYNE4 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 231/437 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs1396321904; called by muse, mutect2, varscan2
- TAF1 | c.4502C>A p.A1501E (on ENST00000373790 / NM_138923.4; = p.A1522E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/286 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as COSV99336627; called by muse, mutect2, varscan2
- ZMAT4 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 226/470 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.092); catalogued as COSV52688967; called by muse, mutect2, varscan2
- BAG6 | c.1442C>A p.T481N | Missense Mutation (SNP) | VAF 238/513 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- CELSR2 | c.2759_2796delinsCTC p.V920Afs*16 | Frame Shift Del (DEL) | VAF 112/592 reads (19%) | called by pindel, varscan2*
- CRTAM | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 131/272 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- DNAH10 | c.11713G>A p.A3905T (on ENST00000409039; = p.A3844T on NM_207437.3) | Missense Mutation (SNP) | VAF 212/478 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, varscan2
- EDNRB | c.1273T>A p.C425S (on ENST00000377211 / NM_001201397.1; = p.C335S on NM_000115.5) | Missense Mutation (SNP) | VAF 23/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- LZTS2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 137/552 reads (25%) | called by muse, varscan2
- RUBCN | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 260/540 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ACER2 | c.78C>T p.I26= | Silent (SNP) | VAF 252/505 reads (50%) | catalogued as rs142611269; called by muse, mutect2, varscan2
- C10orf71 | c.2724C>T p.P908= | Silent (SNP) | VAF 30/668 reads (4%) | catalogued as rs548107137; called by muse, mutect2
- ESX1 | c.624T>G p.T208= | Silent (SNP) | VAF 363/742 reads (49%) | called by muse, mutect2, varscan2
- FBXL19 | c.1827C>T p.H609= | Silent (SNP) | VAF 164/862 reads (19%) | catalogued as rs531482894; called by muse, mutect2, varscan2
- MUC5B | c.11064G>A p.G3688= | Silent (SNP) | VAF 442/944 reads (47%) | called by muse, mutect2, varscan2
- SLC22A3 | c.1404C>T p.F468= | Silent (SNP) | VAF 26/318 reads (8%) | catalogued as rs778036435, COSV51709773, COSV51713180; called by muse, mutect2
- ZC3H7B | c.702G>A p.L234= | Silent (SNP) | VAF 177/864 reads (20%) | called by muse, mutect2, varscan2
- ZNF536 | c.1908C>T p.C636= | Silent (SNP) | VAF 280/547 reads (51%) | catalogued as rs763902544, COSV100835870, COSV62822641; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+3088G>T | Intron (SNP) | VAF 207/440 reads (47%) | called by muse, mutect2, varscan2
